Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3WW, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3WW-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Patient Name:

Accession #:

Med. Rec. #:

Date of Procedure:

DOB: (Age):

Location:

Date of Receipt:

Gender:

Service: Urology

Date of Report:

Ref. Physician:

Account #:

Patient Address:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

History of bladder carcinoma.

1cD-0-3

Carcinoma, urothelial, NOS 8120/3

Path Site: bladder, NOS C67.9

CQCF: bladder, wall, posterior C67.4

hw
6/10/12

Specimens Submitted:

- 1: Right common iliac lymph nodes
- 2: Left common iliac lymph nodes
- 3: Right distal pelvic lymph nodes
- 4: Left distal pelvic lymph nodes
- 5: Pre sacral lymph nodes
- 6: Bladder, prostate, seminal vesicles perivesicle lymph nodes, urachus
- 7: Right distal pelvic lymph nodes # 2
- 8: Left distal ureter
- 9: Right distal ureter

DIAGNOSIS:

1. Right common iliac lymph nodes:

Part # 1

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 6

Number of lymph nodes with metastatic disease: 0

2. Left common iliac lymph nodes:

Part # 2

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 7

Number of lymph nodes with metastatic disease: 0

3. Right distal pelvic lymph nodes:

Part # 3

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 11

Number of lymph nodes with metastatic disease: 0

4. Left distal pelvic lymph nodes:

Part # 4

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 16

Number of lymph nodes with metastatic disease: 0

hw
6/10/12

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

5. Pre sacral lymph nodes:

Part # 5

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 2

Number of lymph nodes with metastatic disease: 0

6. Bladder, prostate, seminal vesicles perivesicle lymph nodes, urachus:

Part # 6

Tumor Type:

Urothelial carcinoma with mixed histologic features, including: sarcomatoid and squamous differentiation arising from a diverticulum

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

In situ component not identified

Pattern of growth of the Invasive component:

Diffuse

Tumor Multicentricity:

Identified

Bladder Local Invasion:

Perivesical soft tissues

Soft tissue surrounding diverticulum

Extravesical Tumor Extension:

Ureters uninvolved

Urethra uninvolved

Vascular Invasion:

Not identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Exhibiting chronic cystitis

Exhibiting changes of prior procedure

Prostate:

Nodular hyperplasia

Seminal Vesicles:

Not involved

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC

pT3 (Invasion of perivesicle soft tissue)

PR0 (No involvement of prostate)

7. Right distal pelvic lymph nodes # 2:

Part # 7

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 5

Number of lymph nodes with metastatic disease: 0

8. Distal ureter, left; excision:

-Benign segment of ureter.

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

9. Distal ureter, right; excision:
-Benign segment of ureter.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "right common iliac lymph nodes", and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 1.6 cm in greatest dimension. The specimen including identified lymph nodes is entirely submitted.

Summary of sections:

BLN - bisected lymph node

LN - lymph nodes

F - adipose tissue

2) The specimen is received fresh, labeled "left common iliac lymph nodes", and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 3.0 cm in greatest dimension. The specimen including identified lymph nodes is entirely submitted.

Summary of sections:

SLN - serially sectioned lymph node

LN - lymph nodes

F - adipose tissue

3) The specimen is received fresh, labeled "right distal pelvic lymph nodes", and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 10.0 cm in greatest dimension. The specimen including identified lymph nodes is entirely submitted.

Summary of sections:

SLN - serially sectioned lymph node

LN - lymph nodes

F - adipose tissue

4) The specimen is received fresh, labeled "left distal pelvic lymph nodes", and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 6.0 cm in greatest dimension. All identified lymph nodes are entirely submitted.

Summary of sections:

SLN - serially sectioned lymph node

BLN - bisected lymph node

LN - lymph nodes

F - adipose tissue

5) The specimen is received fresh, labeled "presacral lymph nodes", and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 2.5 cm in greatest dimension. The specimen including identified lymph nodes is entirely submitted.

Summary of sections:

LN - lymph nodes

F - adipose tissue

6) The specimen is received fresh, labeled "Bladder, prostate, seminal vesicles, perivesical lymph nodes urachus". It consists of a radical cystectomy specimen measuring 15 cm from superior to inferior 15 cm laterally and 8 cm from anterior to posterior. The bladder measures 16 x 10 x 8 cm, the prostate measures 4 x 3 x 3 cm, the right seminal vesicle measures 3 x 1.2 x 0.9, the right vas deferens measures 4 x 0.7, the left seminal vesicle measures 5 x 2.5 x 1 cm, and the left vas deferens measures 3 x 0.6 cm. The anterior aspect of the bladder is inked black and the posterior blue. The prostatic urethral margin is shaved and submitted.

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

The bladder is opened along the anterior midline to reveal a gray tan fleshy necrotic mass measuring 8.5 x 6.5 x 5 cm which is situated within a distended diverticulum, which protrudes through a 3.5 x 3cm open defect located 2.5 cm above the right ureteral orifice, to the bladder mucosa. The mass is located 3.5cm from the left orifice and 2cm from the right orifice. Both ureters are probe patent, measuring up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal a gray tan necrotic mass, which extends to the inked fat. Not additional lesion is grossly identified. The remaining bladder edematous congested and not other lesion is identified. Discrete perivesical lymph nodes are not identified. The prostate is serially sectioned to reveal a white whorled firm cut surface. Representative submitted including three sections from each prostatic quadrant and transition zone. The specimen is photographed. was submitted.

Summary of sections:

UTHM - urethral margin
RUM - right ureter margin
LUM - left ureter margin
L- lesion
RUO - right ureter orifice
LUO - left ureter orifice
LP - left posterior wall
LA - left anterior wall
RP - right posterior wall
RA - right anterior wall
TRI - trigone
DOM - dome
F - perivesical fat
RSV - right seminal vesicle
LSV - left seminal vesicle
RAP - right apex prostate
LAP - left apex prostate
RAM - right anterior mid prostate
RPM - right posterior mid prostate
LAM - left anterior mid prostate
LPM - left posterior mid prostate
RAB - right anterior base prostate
RPB - right posterior base prostate
LAB - left anterior base prostate
LPB - left posterior base prostate
DW - diverticulum wall

7) The specimen is received fresh, labeled "right distal pelvic lymph nodes #2", and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 2.4 cm in greatest dimension. The specimen including identified lymph nodes is entirely submitted.

Summary of sections:

LN - lymph nodes
BLN - bisected lymph node
F - adipose tissue

8) The specimen is received in formalin, labeled "left distal ureter unclipped end is the margin", and consists of a segment of ureter and attached soft tissue with one clipped end and one unclipped end. The ureter is 4.0 cm in length and 0.5 cm in diameter. The ureter is serially sectioned and reveals a patent lumen and smooth tan mucosa. The specimen is entirely submitted.

Summary of sections:

M - margin from unclipped end
U - undesignated

9) The specimen is received in formalin, labeled "right distal ureter unclipped end is the margin", and consists of a segment of ureter and attached soft tissue with one clipped end and one unclipped end. The ureter is 4.3 cm in length and 0.5 cm in diameter. The ureter is serially sectioned and reveals a patent lumen and smooth tan mucosa. The specimen is entirely submitted.

Summary of sections:

M - margin from unclipped end
U - undesignated

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Summary of Sections:**Part 1: Right common iliac lymph nodes**

Block	Sect. Site	PCs
2	BLN	4
2	F	2
1	LN	2

Part 2: Left common iliac lymph nodes

Block	Sect. Site	PCs
1	F	2
2	LN	6
2	SLN	7

Part 3: Right distal pelvic lymph nodes

Block	Sect. Site	PCs
1	F	2
2	LN	6
3	SLN	9

Part 4: Left distal pelvic lymph nodes

Block	Sect. Site	PCs
7	BLN	14
1	F	2
2	LN	6
3	SLN	9

Part 5: Pre sacral lymph nodes

Block	Sect. Site	PCs
1	F	1
1	LN	2

Part 6: Bladder, prostate, seminal vesicles perivesicle lymph nodes, urachus

Block	Sect. Site	PCs
1	DOM	1
1	DW	2
1	F	1
9	L	9
1	LA	1
1	LAB	1
1	LAM	1
1	LAP	1
1	LP	1
1	LPM	1
1	LSV	1
1	LUM	1
1	LUO	1
1	RA	1
1	RAB	1
1	RAM	1
1	RAP	1
1	RP	1
2	RPB	2
1	RPM	1
1	RSV	1

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

1	RUM	1
1	RUO	1
1	TRI	1
1	UTHM	1

Part 7: Right distal pelvic lymph nodes # 2

Block	Sect. Site	PCs
2	BLN	4
1	F	1
1	LN	2

Part 8: Left distal ureter

Block	Sect. Site	PCs
1	M	1
2	U	6

Part 9: Right distal ureter

Block	Sect. Site	PCs
1	M	1
2	U	8

Source: NCI Genomic Data Commons file d3704326-3245-4116-a0a9-af106a22adb0 (TCGA-DK-A3WW.5EA5657B-39DE-49F8-BFFF-AC48B4491370.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).